TARGET case TARGET-30-PALNLU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12722454-2ce0-5074-aca4-096fd9e79433

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 954 days (2.6 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.0; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 3.9 years (1,439 days); Year of diagnosis: 2002; Days to last follow up: 954 days (2.6 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL0321.
   Treatment given: Protocol identifier: A3973.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 538 days (1.5 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 538 days (1.5 years); First event: Relapse.
- Days to follow up: 538 days (1.5 years); Progression or recurrence anatomic site: Pelvis, NOS.
- Days to follow up: 954 days (2.6 years); Year of follow up: 2004.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PALNLU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALNLU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 954
- Protocol: ANBL00B1, A3973, ANBL0032, ANBL0321
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.49
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Head, face or neck, NOS Cheek, NOS Jaw, NOS Nose, NOS Cervical region, NOS Supraclavicular region, NOS
- Site of Relapse: Bone Marrow; Other, specify: pelvis
